Surgical pathology report (de-identified scan), TCGA case TCGA-D9-A6EA, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D9-A6EA-06A (Metastatic).

Department of Cancer Pathology

Patient: XXX

Age:

Gender: M

Examination result No.

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion) Metastases to lymph nodes of the right axilla

State post removal of melanoma of the back skin (SNB-).

Date of admission:

100-0-3
Melanoma, malignant NOS
8720/3
Site Axillary lymph node
Q77.3
JW 6/25/13

Material:

1) Material: axillary lymph nodes, right axillary lymph nodes. State post removal of melanoma. Method of collection:

Total organ resection

Histopathological diagnosis

Examination performed on:

Metastases of malignant melanoma to 6/15 lymph nodes. (8720/6 T-08710)*

* codes according to ICD-O-3 or SNOMED

Macroscopic description:

Lymph nodes of 3cm in length.

Assistant:

Pathologist:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 0874a064-4c07-481b-a143-f86d151a9359 (TCGA-D9-A6EA.78D2592F-845C-4A33-AC8B-48C109E4D50B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).